Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5182, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5182-01A (Primary Tumor).

[page 1 of 4]
Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 5182

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: SP: Kidney, left, partial nephrectomy

2: SP: Kidney, left renal margin, biopsy

3: SP: Bone, left 11th rib, partial resection

4: SP: Soft tissue, left peri-nephric, biopsy

5: SP: Soft tissue, over tumor, left kidney, biopsy

6: SP: Lymph node, left hilar, biopsy

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.0 cm. ✓

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is also not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Kidney, left renal margin, biopsy

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Benign renal parenchyma

3. SP: Bone, left 11th rib, partial resection
Benign segment of rib
4. SP: Soft tissue, left peri-nephric, biopsy
Benign fibroadipose tissue
5. SP: Soft tissue, periapical, left kidney, biopsy
Benign fibroadipose tissue
6. SP: Lymph node, left hilar, biopsy
Not identified
Benign fibroadipose tissue; entirely submitted

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "Left renal mass". It consists of a 5 x 3.5 x 3.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked blue and the specimen is serially sectioned to reveal a fairly circumscribed, hemorrhagic to yellow and focally calcified tumor measuring 3 x 2.2 x 2 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. The specimen is photographed

Summary of sections:
FSC - frozen section control
T - tumor
M - margin
L - representative sections

2). The specimen is received fresh for frozen section consultation, labeled "Left renal margin" and consists of a fragment of pink tan soft tissue measuring 0.3 x 0.3 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

3). The specimen is received fresh, labeled "Portion of left eleven Rib" and consists of a segment of rib measuring 7.5 x 1.2 x 0.6 cm. Red, tan soft tissue is attached. The specimen is bisected to reveal a homogenous red tan granular and bony cut surface. The cortical surface appears intact, and no discrete lesions are noted. Representative sections are submitted for decalcification.

Summary of sections:
U -- undesignated

[page 3 of 4]
4). The specimen is received fresh, labeled "Perinephric fat" and consists of several irregularly shaped pieces of yellow tan lobulated adipose tissue measuring 18 x 12 x 0.5 cm in aggregate. No abnormalities are noted. Representative section are submitted.

Summary of sections:

U -- undesignated

5). The specimen is received in formalin labeled, "fat over tumor left the kidney", and consists of multiple pieces of adipose tissue measuring 6 x 6 x 2 cm in aggregate. Representative sections are submitted.

Summary of sections:

U-- undesignated

6). The specimen is received in formalin labeled, "left hilar lymph node", and consists of 2 pieces of fatty lymphoid tissue measuring 2.0 x 1.5 x 0.4 cm and 1.5 about 1.0 x 0.4 cm respectively. The specimen is entirely submitted.

Summary of sections:

LN—lymph nodes

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy ()

Block	Sect. Site	PCs
1	FSC	1
1	L	1
1	M	1
2	T	2

Part 2: SP: Kidney, left renal margin, biopsy ()

Block	Sect. Site	PCs
1	FSC	1

Part 3: SP: Bone, left 11th rib, partial resection ()

Block	Sect. Site	PCs
1	U	1

Part 4: SP: Soft tissue, left peri-nephric, biopsy ()

Block	Sect. Site	PCs
1	U	1

Part 5: SP: Soft tissue, over tumor, left kidney, biopsy ()

Block	Sect. Site	PCs
1	u	1

Part 6: SP: Lymph node, left hilar, biopsy ()

Block	Sect. Site	PCs
2	In	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative

[page 4 of 4]
[REDACTED]

consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR. FAVOR CONVENTIONAL RENAL CELL CARCINOMA,
NEGATIVE MARGIN. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN KIDNEY [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 8ef480d0-c674-458c-b48a-b473e31ffd93 (TCGA-BP-5182.9B83A81C-F9A2-494F-A478-AC28BDDA707B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).